Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4989, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4989-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4989

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

1: SP: Kidney, right with tumor, radical nephrectomy

2: SP: Lymph nodes, paracaval and precaval, excision

3: SP: Adrenal, right, excision

DIAGNOSIS:

PENDING ADDITIONAL SECTIONS FROM RENAL VEIN

1. SP: Kidney, right with tumor, radical nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 6.2 cm.

Local Invasion (for renal cortical types):

Extends through renal capsule but confined within Gerota's fascia

Renal Vein Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT3 Tumor extends into major veins or invades the adrenal gland or perinephric tissues, but not beyond Gerota's fascia

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

2. SP: Lymph nodes, paracaval and precaval, excision

Lymph Nodes:

Not involved

Number of nodes examined: 10

3. SP: Adrenal, right, excision:

Benign adrenal gland

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh, labeled "Right kidney and tumor" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 477.5 g post fixation. The kidney measures 11.7 x 8.4 x 4.2 cm. The renal capsular surface is smooth pink-tan, with a smooth bulging nodular area identified in the area of the hilum. The attached ureter measures 1.7 cm in length and 0.4 cm in diameter. The attached renal vein measures 0.5 cm in length and 0.9 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and blvalved to reveal an ill-defined red-tan tumor mass measuring 6.2 x 4.9 x 3.2 cm, which is located at the superior pole of the kidney, extending to but not grossly involving the renal pelvis and renal sinus. On sectioning, an ill-defined white tan fibrotic area is identified within the mass measuring 2.7 cm in greatest dimension. On sectioning, the tumor focally involves the renal vein, with a 0.2, and 0.7 cm red-tan bulging area identified at the endothelial lining. The tumor does not grossly involve the inked perinephric margin, or hilum and hilar fat. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 0.7 cm. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections and photographs have been taken.

Summary of sections:

UVM -- ureteral and vessel margins

RST-- tumor

TWF -- tumor with fat

TH-- tumor with hilar fat

RS -- tumor with sinus fat

RP -- tumor with renal pelvis

NK -- representative sections kidney

VI-entire area of vascular invasion

2). The specimen is received in formalin, labeled "paracaval and pericaval lymph node" and consists of multiple suspected lymph nodes measuring up to 1.0 cm. Entirely submitted.

Summary of sections

LN -- suspected lymph nodes

3). The specimen is received in formalin, labeled "right adrenal gland" and consists of a adrenal gland measuring 6 x 2 x 0.8 cm and weighing 13 g. Cut sections of adrenal gland is grossly unremarkable. Representative sections are submitted.

Summary of sections

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

U. -- undesignated

Summary of Sections:

Part 1: SP: Kidney, right with tumor, radical nephrectomy [REDACTED]

Block	Sect. Site	PCs
1	nk	1
1	rp	1
1	rs	1
5	rst	5
1	th	1
1	twf	1
1	uvm	1
3	vi	0

Part 2: SP: Lymph nodes, paracaval and precaval, excision [REDACTED]

Block	Sect. Site	PCs
2	LN	2

Part 3: SP: Adrenal, right, excision [REDACTED]

Block	Sect. Site	PCs
2	U	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: CONSISTENT WITH RENAL CELL CARCINOMA, GROSS EXAMINATION ONLY.
[REDACTED]
PERMANENT DIAGNOSIS: SAME
- [REDACTED]

Source: NCI Genomic Data Commons file de6e6400-68e4-430a-8375-a5e0c9ef10bf (TCGA-BP-4989.4DCBE89B-3AC2-482F-A9AE-01A25E41D1CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).